Gene-level copy-number profile of tumor specimen C3N-03884-02 from CPTAC case C3N-03884, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 64.6 years (23,590 days).
Specimen C3N-03884-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 93d8c440-1484-4eff-90e7-b603232599e5.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-03884-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,225 have no estimate.
https://portal.gdc.cancer.gov/files/4c3a11bb-3ec5-494e-8105-8aca3c5bfae6

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 7,397; copy number 2: 48,723; copy number 3: 2,099; copy number 4: 15; copy number 5: 4; copy number 6: 59; copy number 7: 19; copy number 8: 81.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 163 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:115,031,273–117,019,679, 45 genes, copy number 5–6: AC094104.2, AC094104.1, TRIM36, TRIM36-IT1, AC008494.2, PGGT1B, AC008494.3, AC008494.1, CCDC112, HMGN1P15, CTNNA1P1, AK3P4, AC008628.2, AC008628.1, CCT5P1, FEM1C, TICAM2, TMED7-TICAM2, AC010226.1, TMED7, AC008549.2, AC008549.1, H3P24, RNU2-49P, CDO1, ATG12, AP3S1, LVRN, DDX43P1, ARL14EPL, AC034236.1, AC034236.3, AC034236.2, COMMD10, RNU6-644P, HMGN2P27, AC018752.1, SEMA6A, SEMA6A-AS1, RPS14P8, SEMA6A-AS2, RPS17P2, LINC02214, AC010267.1, AC093534.1.
- chr6:70,216,040–71,652,611, 32 genes, copy number 6–8: COL9A1, AL160262.1, AL365226.1, FAM135A-AS1, FAM135A, RNU7-48P, SDHAF4, AL583856.2, AL583856.1, SLC25A6P6, SMAP1, AL354943.1, NDUFAB1P1, B3GAT2, BECN1P2, U3, LYPLA1P3, RNU6-411P, AL589935.1, AL589935.3, AL589935.2, OGFRL1, AL136164.2, AL136164.1, LINC00472, MIR30C2, AL136164.3, MIR30A, LINC01626, AL035467.1, KRT19P1, RNU4-66P.
- chr6:78,604,467–79,278,427, 9 genes, copy number 6: AL121718.1, AL450327.1, IRAK1BP1, PHIP, AL356776.1, AL356776.2, HMGN3, HMGN3-AS1, AL355796.1.
- chr9:27,829,276–27,944,497, 2 genes, copy number 6: AL360014.1, AL353746.1.
- chr17:62,264,705–64,020,634, 75 genes, copy number 5–8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 5,054. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
